Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A430, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A430-01A (Primary Tumor).

Procurement Date: Laterality: Tumor Features: Ulcerated, Tumor Extent: Reticular dermis invaded (Clark's level IV), Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 1.8 x 0 x 2.5 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Nodular melanoma

Histologic grade: Poorly differentiated

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Clark's level IV, Breslow's depth -- 1.8 cm.

ICD-O3

melanoma, nodular

8721/3

Site: skin, trunk

C44.5

8-3-12
RD

Source: NCI Genomic Data Commons file 959afc2b-8769-457a-b13e-ea1c5d38e716 (TCGA-EB-A430.CAF377CF-8A98-4334-B6A7-831024B5A5A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).